Somatic mutation profile of tumor specimen TCGA-D1-A16X-01A (aliquot TCGA-D1-A16X-01A-11D-A12J-09) from TCGA case TCGA-D1-A16X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.2 years (19,799 days).
Specimen TCGA-D1-A16X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 946ef25a-0806-4e11-b87b-667980cc513d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16X-10A (Blood Derived Normal), aliquot TCGA-D1-A16X-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21295832-cf0d-402d-a040-b6096da86023

The open-access MAF lists 2,949 somatic variants for this specimen: 2,348 protein-altering or splice-affecting, 544 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,946, Silent 544, Nonsense Mutation 349, Splice Site 32, Intron 26, RNA 20, Splice Region 16, 5'UTR 4, 5'Flank 3, 3'UTR 3, Nonstop Mutation 2, Frame Shift Ins 2.

Variants (750 of 2,949; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 62/202 reads (31%) | catalogued as rs764742792, CM050554, COSV60684823; ClinVar: likely pathogenic; called by muse, varscan2
- EPG5 | c.2575G>T p.E859* | Nonsense Mutation (SNP) | VAF 36/134 reads (27%) | catalogued as rs587776941, CM1212059, COSV56346108; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852364, CM055225, CM890046, COSV64270460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F9 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs137852247, CM1314241, CM940587, COSV54378539; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2066G>A p.R689Q (on ENST00000281708 / NM_001349798.2; = p.R609Q on NM_018315.5) | Missense Mutation (SNP) | VAF 68/298 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55900091; called by muse, varscan2
- KCNQ5 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 36/516 reads (7%) | catalogued as rs1554201137, COSV59651569; ClinVar: likely pathogenic; called by muse, mutect2
- MTHFR | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs574132670, CM155651, COSV64701534, COSV64701602; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MTOR | c.5664C>A p.F1888L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63869154, COSV63870934; called by muse, mutect2, varscan2
- PIK3CB | c.3199G>T p.D1067Y | Missense Mutation (SNP) | VAF 44/150 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56684065, COSV56687870; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 63/197 reads (32%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 89/273 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 7/145 reads (5%) | catalogued as rs1567785872, COSV99542479; ClinVar: pathogenic; called by muse, mutect2
- SRCAP | c.8242C>T p.R2748* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1085307899, CM136744, COSV52668892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TARBP2 | c.571G>T p.E191* (on ENST00000266987 / NM_134323.2; = p.E170* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | hotspot (GDC flag); catalogued as COSV57199177; called by muse, mutect2, varscan2
- TTN | c.74371C>T p.R24791* (on ENST00000591111; = p.R17367* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs774411587, COSV59903609; ClinVar: likely pathogenic; called by mutect2, varscan2
- AADACL2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs766584533, COSV62929738; called by muse, mutect2, varscan2
- AAK1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773204637, COSV68641788; called by muse, mutect2, varscan2
- AASDH | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as rs765349701, COSV52704659; called by muse, mutect2, varscan2
- AASDHPPT | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53788482, COSV99593144; called by muse, mutect2, varscan2
- AATF | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199725061; called by muse, varscan2
- ABCA10 | c.3137G>A p.G1046D | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as COSV52219371; called by muse, mutect2, varscan2
- ABCA13 | c.2500T>G p.L834V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV70026535; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA6 | c.1628A>C p.K543T | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV52636545; called by muse, mutect2, varscan2
- ABCA6 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99446683; called by muse, mutect2
- ABCA9 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266827951, COSV100383180; called by muse, mutect2
- ABCA9 | c.1500G>T p.L500F | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60621842; called by muse, mutect2, varscan2
- ABCB7 | c.1922C>T p.S641L (on ENST00000373394 / NM_001271696.3; = p.S642L on NM_004299.6) | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1002483499, COSV99504453; called by muse, mutect2
- ABCC2 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755485165, COSV64984961; called by muse, mutect2, varscan2
- ABCC2 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64984964; called by muse, mutect2, varscan2
- ABCC2 | c.2954C>T p.A985V | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1438672389, COSV64984969; called by muse, mutect2, varscan2
- ABCC4 | c.2459G>T p.R820I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs11568659; called by muse, mutect2, varscan2
- ABCC6 | c.3105C>A p.F1035L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52742009, COSV99229129; called by muse, mutect2, varscan2
- ABCD1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781983308, COSV54383748; ClinVar: uncertain significance; called by muse, varscan2
- ABCG2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770618556, COSV52944150; called by muse, mutect2, varscan2
- ABHD17B | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100330229; called by muse, mutect2, varscan2
- ABHD5 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50006535, COSV50007131; called by muse, mutect2
- ABI3BP | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.197); catalogued as COSV52530538; called by muse, mutect2, varscan2
- ABLIM1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV53301842; called by muse, mutect2, varscan2
- AC008676.3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as rs780016703, COSV56635975; called by muse, mutect2, varscan2
- AC090517.4 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50996010; called by muse, mutect2, varscan2
- AC092718.8 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59601465; called by muse, varscan2
- AC126283.2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 59/272 reads (22%) | catalogued as COSV67097984, COSV67099039; called by muse, mutect2, varscan2
- ACACA | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1357271377; called by muse, mutect2, varscan2
- ACACB | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs774959869, COSV58129464, COSV58130111; called by muse, mutect2, varscan2
- ACAN | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs755142678, COSV61357447; called by muse, mutect2, varscan2
- ACAP2 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV100462251; called by muse, mutect2
- ACAP2 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 97/412 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV58750006; called by muse, mutect2, varscan2
- ACAT2 | c.662T>G p.F221C | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58457776; called by muse, mutect2, varscan2
- ACKR1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.204); catalogued as COSV63672081; called by muse, mutect2, varscan2
- ACO1 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs776806842, COSV59377682; called by muse, mutect2, varscan2
- ACSL4 | c.695C>T p.A232V (on ENST00000340800 / NM_022977.2; = p.A191V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV61613629; called by muse, mutect2, varscan2
- ACSL5 | c.1380G>A p.W460* (on ENST00000354273; = p.W516* on NM_016234.3) | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV61129388; called by muse, mutect2, varscan2
- ACSL6 | c.844A>G p.N282D (on ENST00000379240; = p.N307D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV57295532; called by muse, mutect2, varscan2
- ACSM2B | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs150327444, COSV61657515; called by muse, mutect2
- ACSM3 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs769922075, COSV55500324; called by muse, mutect2, varscan2
- ACSM3 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV55500332; called by muse, mutect2, varscan2
- ACSM4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | catalogued as COSV68066592; called by muse, mutect2, varscan2
- ACTA2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1306745024, COSV56515849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTL7A | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758729154, COSV61776227; called by mutect2, varscan2
- ACTN2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1060503683, COSV63973082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTRT2 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65759018; called by muse, mutect2, varscan2
- ADA | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs779530705, COSV63068738; called by muse, mutect2, varscan2
- ADAM18 | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55844935; called by muse, mutect2, varscan2
- ADAM21 | c.1551T>G p.I517M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV50789333; called by muse, mutect2, varscan2
- ADAM23 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV52209973; called by muse, mutect2, varscan2
- ADAM28 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99737256; called by muse, mutect2
- ADAM28 | c.1469T>C p.F490S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99738851; called by muse, mutect2
- ADAMTS19 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV50735078; called by muse, varscan2
- ADAMTS2 | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 19/498 reads (4%) | catalogued as COSV52382964, COSV99282634; called by muse, mutect2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- ADCK1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs766265393, COSV53079027; called by muse, mutect2, varscan2
- ADCY1 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52031572; called by muse, mutect2, varscan2
- ADCY4 | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100156628; called by muse, mutect2, varscan2
- ADCY8 | c.2235C>A p.F745L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53899552; called by muse, mutect2, varscan2
- ADCY8 | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652650; called by muse, mutect2
- ADD3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs770245298, COSV53321061, COSV99523315; called by muse, varscan2
- ADGRB3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65386923; called by muse, mutect2, varscan2
- ADGRB3 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 34/193 reads (18%) | catalogued as COSV65386928; called by muse, mutect2, varscan2
- ADGRB3 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53256345; called by muse, mutect2
- ADGRB3 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1197657726, COSV53232994; called by muse, mutect2
- ADGRE3 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV99506287; called by muse, mutect2
- ADGRG4 | c.3951G>T p.E1317D | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1349230323, COSV54967115; called by muse, mutect2
- ADGRG4 | c.8795G>A p.R2932Q | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs980343377, COSV54951498; called by muse, mutect2, varscan2
- ADGRG6 | c.1780T>G p.L594V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV51588032; called by muse, mutect2, varscan2
- ADGRL2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV54652616, COSV54656845; called by muse, mutect2, varscan2
- ADGRV1 | c.10625T>C p.V3542A | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV67980144; called by muse, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV67977934; called by muse, mutect2, varscan2
- ADGRV1 | c.15262G>T p.E5088* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV67980148; called by muse, mutect2, varscan2
- ADNP | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100823766; called by muse, mutect2
- ADNP2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747437164, COSV51536965; called by mutect2, varscan2
- ADRB2 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100019224; called by muse, mutect2
- ADRB2 | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60005272; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 14/392 reads (4%) | catalogued as COSV63694640, COSV63695668; called by muse, mutect2
- AFDN | c.302-1G>T p.X101_splice | Splice Site (SNP) | VAF 34/129 reads (26%) | catalogued as COSV60039646; called by muse, mutect2, varscan2
- AFP | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV56924278, COSV99890056; called by muse, mutect2, varscan2
- AGA | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.478); catalogued as COSV52805850; called by muse, mutect2, varscan2
- AGAP2 | c.1333G>T p.E445* (on ENST00000547588 / NM_001122772.2; = p.E109* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 16/197 reads (8%) | catalogued as rs1555199298, COSV57729863; called by muse, mutect2
- AGK | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs141323107, COSV62595957; called by muse, mutect2, varscan2
- AGTPBP1 | c.1981G>T p.E661* (on ENST00000357081 / NM_001330701.2; = p.E621* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100429381, COSV61269417, COSV61270454; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 57/542 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AHCTF1 | c.4517C>A p.P1506H (on ENST00000366508; = p.P1480H on NM_015446.5) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100403821; called by muse, mutect2
- AHCYL1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV100779600; called by muse, mutect2, varscan2
- AHI1 | c.2478T>G p.I826M | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.535); catalogued as COSV55624135; called by muse, mutect2, varscan2
- AHNAK | c.9592C>T p.P3198S | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99947880; called by muse, mutect2
- AHNAK2 | c.7799C>T p.A2600V | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs376661887; called by muse, mutect2, varscan2
- AHR | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV54121537, COSV99619757; called by muse, mutect2
- AHR | c.2078C>A p.S693Y | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV54122189; called by muse, mutect2, varscan2
- AIFM1 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99781082; called by muse, mutect2
- AK7 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 79/251 reads (31%) | catalogued as COSV50869619; called by muse, mutect2, varscan2
- AKAP11 | c.1198A>C p.K400Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50293503; called by muse, mutect2
- AKAP12 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV53571195, COSV99036990; called by muse, mutect2, varscan2
- AKAP3 | c.1089C>A p.F363L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57414751; called by muse, mutect2, varscan2
- AKAP9 | c.3292G>T p.E1098* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV62340904; called by muse, mutect2, varscan2
- AKR1C4 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs782129542, COSV54122636; called by muse, mutect2, varscan2
- AKR1D1 | c.623T>G p.F208C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54336679; called by muse, mutect2, varscan2
- ALDH1L2 | c.1419A>T p.K473N | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99311104; called by muse, mutect2
- ALDH5A1 | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100708820; called by muse, mutect2, varscan2
- ALOX15B | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs568399473, COSV66479134; called by muse, mutect2, varscan2
- ALOX15B | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370434436; called by muse, mutect2, varscan2
- ALOX5AP | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66857734; called by muse, mutect2, varscan2
- ALOXE3 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV59074410; called by muse, varscan2
- ALPK1 | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99454301; called by muse, mutect2
- ALX1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1374617547, COSV57491539; called by muse, mutect2, varscan2
- AMOT | c.1423G>A p.A475T (on ENST00000371959 / NM_001113490.1; = p.A66T on NM_133265.3) | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59061456; called by muse, mutect2, varscan2
- AMOTL1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54414557; called by muse, mutect2, varscan2
- AMPH | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | catalogued as rs1174104021, COSV57736047; called by muse, mutect2, varscan2
- AMY2B | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796340; called by muse, mutect2
- ANGEL1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.097); catalogued as rs760066871, COSV51871936; called by mutect2, varscan2
- ANGPT4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1433585310, COSV101124682, COSV67920896; called by muse, mutect2, varscan2
- ANK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.333); catalogued as rs538354013, COSV55048293; called by muse, mutect2, varscan2
- ANKEF1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as rs528690112, COSV65692046; called by muse, mutect2, varscan2
- ANKMY2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 50/194 reads (26%) | catalogued as rs529152924, COSV61011244; called by muse, mutect2, varscan2
- ANKRD17 | c.5819C>T p.S1940L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs1427891475, COSV58217009; called by muse, mutect2, varscan2
- ANKRD30A | c.1558C>A p.P520T (on ENST00000611781; = p.P464T on NM_052997.2) | Missense Mutation (SNP) | VAF 132/673 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV64606044; called by muse, mutect2, varscan2
- ANKRD30A | c.2982G>T p.K994N (on ENST00000611781; = p.K938N on NM_052997.2) | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64606049, COSV64610801; called by muse, mutect2, varscan2
- ANKRD34B | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as COSV58613539; called by muse, mutect2, varscan2
- ANKRD50 | c.2243G>A p.G748D | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV72385252; called by muse, mutect2, varscan2
- ANKRD50 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs547546925, COSV72385254; called by muse, mutect2, varscan2
- ANKRD50 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV72385255; called by muse, mutect2, varscan2
- ANKRD50 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs368512857; called by mutect2, varscan2
- ANKS1B | c.3206C>A p.S1069Y (on ENST00000547776 / NM_152788.4; = p.S235Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59116214; called by muse, mutect2, varscan2
- ANO1 | c.1397C>A p.S466Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.871); catalogued as COSV100304121; called by muse, mutect2
- ANO5 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV61082621; called by muse, mutect2, varscan2
- ANOS1 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52916980; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2
- ANXA3 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99363768; called by muse, mutect2
- ANXA5 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634443; called by muse, mutect2
- AOC2 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765645252, COSV53825034; called by mutect2, varscan2
- AP1G2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58110702, COSV58111351; called by muse, mutect2, varscan2
- AP4M1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs770777535, COSV57997606; called by muse, mutect2, varscan2
- APAF1 | c.1799A>C p.K600T (on ENST00000551964 / NM_181861.2; = p.K589T on NM_001160.3) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100244142, COSV59662311; called by muse, mutect2, varscan2
- APBB2 | c.2158C>T p.R720* (on ENST00000295974 / NM_001166050.2; = p.R721* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 117/337 reads (35%) | catalogued as rs1560589921, COSV55948589; called by muse, mutect2, varscan2
- APC | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57349041; called by muse, mutect2
- APC | c.5582C>A p.S1861Y | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD961780, COSV104379185, COSV57328606; called by muse, mutect2, varscan2
- APC | c.8021C>A p.S2674Y | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57331222, COSV99078819; called by muse, mutect2, varscan2
- APEX2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs374701476, COSV58189010; called by muse, varscan2
- APEX2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV58189015; called by muse, varscan2
- APLF | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | catalogued as COSV58143244; called by muse, mutect2, varscan2
- APOA1 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52635430; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOC1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52991437; called by muse, mutect2, varscan2
- APP | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV60995467; called by muse, mutect2, varscan2
- AQP9 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as rs1028882622, COSV54967878; called by muse, mutect2, varscan2
- AQR | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775432905, COSV50030281; called by muse, mutect2, varscan2
- AQR | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50030296; called by muse, mutect2, varscan2
- ARHGAP20 | c.1463T>G p.L488R | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52807925; called by muse, mutect2, varscan2
- ARHGAP21 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as rs1162263953, COSV57603231; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGEF10L | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as rs375108051, COSV51429241; called by muse, mutect2, varscan2
- ARHGEF19 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757203915, COSV54615502; called by mutect2, varscan2
- ARID4A | c.2324A>C p.K775T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.766); catalogued as COSV62162482; called by mutect2, varscan2
- ARL9 | c.481T>C p.Y161H (on ENST00000640821 / NM_001363794.2; = p.Y19H on NM_206919.2) | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as COSV63991081; called by muse, mutect2, varscan2
- ARMC3 | c.429A>C p.K143N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53058271; called by muse, mutect2, varscan2
- ARMC8 | c.190C>T p.P64S (on ENST00000469044 / NM_001363941.2; = p.P50S on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61767896; called by muse, mutect2, varscan2
- ARMCX2 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV57529186; called by muse, mutect2, varscan2
- ARPP21 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51793702; called by muse, mutect2, varscan2
- ARPP21 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs376713321, COSV51793709; called by muse, varscan2
- ARSF | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs866778967, COSV63839147; called by muse, mutect2, varscan2
- ARV1 | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs1290114872, COSV59617563; called by muse, mutect2
- ASAP1 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63045634; called by muse, mutect2, varscan2
- ASB15 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs1338535987, COSV51924436; called by muse, mutect2, varscan2
- ASB2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs375831081; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASCC3 | c.936A>C p.K312N | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV61226540; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, mutect2, varscan2
- ASH1L | c.2615T>G p.I872S | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV64206262, COSV64206473; called by muse, mutect2, varscan2
- ASIC4 | c.1540C>A p.L514I (on ENST00000347842 / NM_182847.3; = p.L533I on NM_018674.6) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.041); catalogued as rs1327452779, COSV61731244; called by muse, mutect2, varscan2
- ASPM | c.10292T>G p.F3431C | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54126264; called by muse, mutect2, varscan2
- ASPM | c.6305C>A p.S2102Y | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54126272; called by muse, mutect2, varscan2
- ASPM | c.5302C>T p.R1768W | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770335356, COSV54126280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPN | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV65015955, COSV65016337; called by muse, mutect2, varscan2
- ASTN1 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as rs1357604735, COSV62493153; called by muse, mutect2, varscan2
- ASTN2 | c.1747C>A p.L583I (on ENST00000313400 / NM_001365069.1; = p.L532I on NM_014010.5) | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV57758716; called by muse, mutect2, varscan2
- ASTN2 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57758738; called by muse, varscan2
- ATAD2 | c.2323T>G p.F775V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54878350; called by muse, mutect2, varscan2
- ATF2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51368882; called by muse, mutect2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 36/186 reads (19%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATIC | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99377870; called by muse, mutect2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATMIN | c.1564C>A p.H522N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV100214650; called by muse, mutect2, varscan2
- ATP10B | c.2702T>G p.I901S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59145717; called by muse, mutect2, varscan2
- ATP11B | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1287322718, COSV60026891; called by muse, mutect2, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV60026901; called by muse, mutect2, varscan2
- ATP11B | c.1067C>A p.S356* | Nonsense Mutation (SNP) | VAF 34/236 reads (14%) | catalogued as COSV60026914; called by muse, mutect2, varscan2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 44/195 reads (23%) | catalogued as rs1295948091, COSV60026923; called by muse, mutect2, varscan2
- ATP11C | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 64/237 reads (27%) | catalogued as rs867529692, COSV59560522; called by muse, mutect2, varscan2
- ATP11C | c.671T>G p.F224C | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59560540; called by muse, mutect2, varscan2
- ATP11C | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59558906, COSV59560563; called by muse, mutect2, varscan2
- ATP2A2 | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58042805; called by muse, mutect2, varscan2
- ATP2B4 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 44/178 reads (25%) | catalogued as COSV58175216; called by muse, mutect2, varscan2
- ATP2C2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV52293684; called by muse, mutect2, varscan2
- ATP6V1D | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV53598973; called by muse, mutect2, varscan2
- ATP6V1H | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 43/210 reads (20%) | catalogued as COSV62217366; called by muse, mutect2, varscan2
- ATP7A | c.2713A>G p.T905A | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV58443737; called by muse, mutect2, varscan2
- ATP8A2 | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs376983357, COSV54962546; called by muse, mutect2, varscan2
- ATP8A2 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV99682352; called by muse, mutect2
- ATP8A2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs748812032, COSV54939414; called by muse, varscan2
- ATP8B4 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 26/306 reads (8%) | catalogued as COSV52709677; called by muse, mutect2
- ATRNL1 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 61/208 reads (29%) | catalogued as COSV61799207; called by muse, mutect2, varscan2
- ATRX | c.3000A>C p.K1000N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV64872983; called by muse, mutect2, varscan2
- AXDND1 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 68/189 reads (36%) | catalogued as COSV62640529; called by muse, mutect2, varscan2
- AXDND1 | c.2755C>A p.L919I | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100858461; called by muse, mutect2
- B3GALT5 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 82/232 reads (35%) | catalogued as COSV58197825; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2
- BANK1 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV59839753; called by muse, mutect2, varscan2
- BCAR1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50779299; called by muse, mutect2, varscan2
- BCAS1 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65084433; called by muse, mutect2, varscan2
- BCL11B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs767394342, COSV100596079, COSV61734180; called by muse, mutect2, varscan2
- BCOR | c.3812C>T p.S1271L (on ENST00000378444 / NM_001123385.2; = p.S1237L on NM_017745.6) | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs892857458, COSV60699397, COSV60715837; called by muse, mutect2, varscan2
- BEND2 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.171); catalogued as COSV66215276; called by muse, mutect2, varscan2
- BEND5 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 132/413 reads (32%) | catalogued as COSV65716578; called by muse, mutect2, varscan2
- BEX1 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.925); catalogued as COSV65579974; called by muse, mutect2, varscan2
- BFSP2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | catalogued as rs1296755444, COSV56587827; called by muse, mutect2
- BICC1 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100874864; called by muse, mutect2
- BICC1 | c.1187T>G p.I396S | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54062541; called by muse, mutect2, varscan2
- BICD2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs1338473700, COSV63548221; called by muse, mutect2, varscan2
- BICDL2 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868651357, COSV99560650; called by muse, mutect2
- BIRC6 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1451029366, COSV101428386, COSV70197739; called by muse, mutect2
- BIRC6 | c.8383C>T p.R2795* | Nonsense Mutation (SNP) | VAF 15/372 reads (4%) | catalogued as COSV70202143; called by muse, mutect2
- BIRC6 | c.12686A>G p.D4229G | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70196661; called by muse, mutect2, varscan2
- BMP2K | c.1979A>C p.D660A | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV55008866; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMPER | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51813496; called by muse, mutect2, varscan2
- BMX | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV100564494; called by muse, mutect2
- BPHL | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.734); catalogued as rs1159825189, COSV66743151; called by muse, mutect2, varscan2
- BPIFB1 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99487425; called by muse, mutect2
- BPIFB3 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64956959; called by muse, mutect2, varscan2
- BRAF | c.1666T>C p.F556L (on ENST00000288602 / NM_001374244.1; = p.F516L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962884; called by muse, mutect2
- BRAF | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as COSV56101984; called by muse, mutect2, varscan2
- BRAF | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.105); catalogued as rs730880413, COSV56101990; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7481G>A p.R2494Q | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs80358973, COSV66449976; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.3614A>G p.K1205R | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.628); catalogued as COSV51995762; called by muse, mutect2, varscan2
- BRIP1 | c.3337A>G p.K1113E | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as COSV52003696; called by muse, mutect2
- BRWD1 | c.6809G>A p.R2270Q | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1387048628, COSV59000046; called by muse, mutect2, varscan2
- BRWD3 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs755270226, COSV64745068; called by muse, mutect2, varscan2
- BRWD3 | c.4236C>A p.I1412= | Splice Region (SNP) | VAF 9/228 reads (4%) | catalogued as COSV100955926; called by muse, mutect2
- BRWD3 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100956639, COSV64745075; called by muse, mutect2, varscan2
- BTBD7 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100108059; called by muse, mutect2
- BTBD7 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV54134422; called by muse, mutect2, varscan2
- BTN3A1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV50024545; called by muse, mutect2, varscan2
- BTN3A3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs138755245; called by muse, mutect2, varscan2
- BTRC | c.1363A>G p.T455A (on ENST00000370187 / NM_033637.4; = p.T419A on NM_003939.5) | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV64579003; called by muse, mutect2, varscan2
- BUB1B | c.2589T>G p.I863M | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV55010539; called by muse, mutect2, varscan2
- C10orf71 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368058122, COSV100110672; called by muse, mutect2, varscan2
- C10orf90 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV52950938; called by muse, mutect2, varscan2
- C12orf4 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs781358792, COSV54206030; called by muse, mutect2, varscan2
- C12orf50 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 62/290 reads (21%) | catalogued as rs200677856, COSV53893431, COSV53897104; called by muse, mutect2, varscan2
- C12orf50 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV53893970; called by muse, mutect2, varscan2
- C14orf39 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147627198, COSV58779891; called by mutect2, varscan2
- C16orf46 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs145595395; called by muse, mutect2, varscan2
- C16orf70 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs776122798, COSV54625397, COSV54627728; called by muse, mutect2, varscan2
- C17orf80 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV52145272; called by muse, mutect2, varscan2
- C1GALT1C1 | c.415T>G p.W139G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58973849; called by muse, mutect2, varscan2
- C1orf105 | c.407-1G>T p.X136_splice | Splice Site (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100877962; called by muse, mutect2
- C1orf158 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55346239; called by muse, mutect2
- C1orf52 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53998436; called by muse, mutect2, varscan2
- C1orf74 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1204565302, COSV50550905; called by muse, mutect2, varscan2
- C1orf87 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 60/190 reads (32%) | catalogued as COSV64596381; called by muse, mutect2, varscan2
- C2CD5 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 101/461 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs750393334, COSV61723353; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2CD6 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 86/390 reads (22%) | catalogued as rs748210926, COSV53792214; called by muse, mutect2, varscan2
- C2orf16 | c.2366C>A p.S789Y | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62678136; called by muse, mutect2
- C2orf16 | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs557771429, COSV62673324; called by muse, mutect2, varscan2
- C2orf73 | c.172A>G p.N58D | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV58310238; called by muse, mutect2, varscan2
- C2orf78 | c.1950C>A p.F650L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753364861, COSV68516704, COSV68519366; called by muse, mutect2, varscan2
- C3 | c.3382G>T p.E1128* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV55569757, COSV55570157, COSV99837235; called by muse, mutect2, varscan2
- C4orf33 | c.411T>G p.I137M | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99828952; called by muse, mutect2
- C4orf51 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV71263879; called by muse, mutect2, varscan2
- C5orf22 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV100323516; called by muse, mutect2
- C6 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 51/194 reads (26%) | catalogued as COSV54706775, COSV54712050, COSV54720400; called by muse, mutect2, varscan2
- C6orf58 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as COSV100314756, COSV61666696; called by muse, mutect2
- C9orf24 | c.281-1G>A p.X94_splice | Splice Site (SNP) | VAF 15/269 reads (6%) | catalogued as COSV99897979; called by muse, mutect2
- C9orf72 | c.247A>C p.K83Q | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101186523; called by muse, mutect2
- CA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 95/486 reads (20%) | catalogued as rs373804439, COSV56277599; called by muse, mutect2, varscan2
- CA5B | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100590742; called by muse, mutect2
- CAB39 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779895273, COSV51474895; called by muse, mutect2, varscan2
- CABLES1 | c.1238G>T p.R413I (on ENST00000256925 / NM_001100619.2; = p.R148I on NM_138375.2) | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56931300; called by muse, mutect2, varscan2
- CABP5 | c.234G>T p.M78I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1163091329, COSV53152190, COSV53154049; called by muse, mutect2, varscan2
- CACNA1B | c.3591G>T p.E1197D | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99497965; called by muse, mutect2
- CACNA1E | c.5339G>T p.R1780I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV62385134; called by muse, mutect2, varscan2
- CACNA2D1 | c.1769C>A p.T590N (on ENST00000356253 / NM_001366867.1; = p.T571N on NM_000722.4) | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV62374956; called by muse, varscan2
- CACNA2D1 | c.1723C>T p.R575* (on ENST00000356253 / NM_001366867.1; = p.R556* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 31/235 reads (13%) | catalogued as rs730880057, COSV62374963; called by muse, varscan2
- CACNA2D4 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201110560, COSV54946604; called by muse, mutect2, varscan2
- CADPS | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761723810, COSV51871014; called by mutect2, varscan2
- CAGE1 | c.1093A>C p.I365L (on ENST00000512086; = p.I229L on NM_205864.3) | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57075456; called by muse, mutect2, varscan2
- CAMK1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs749586067, COSV56537881; called by muse, mutect2, varscan2
- CAMK1D | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs763942938, COSV66608333; called by muse, mutect2, varscan2
- CAMK1D | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66608344; called by muse, mutect2, varscan2
- CAMKMT | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1020249685, COSV65923997; called by muse, mutect2, varscan2
- CAMKV | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56554385; called by muse, mutect2, varscan2
- CAND1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs752643654, COSV73338558; called by muse, mutect2, varscan2
- CAPN13 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99700330; called by muse, mutect2
- CAPN2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs768082890, COSV54334084; called by mutect2, varscan2
- CAPSL | c.485T>G p.F162C | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101274270; called by muse, mutect2, varscan2
- CARD6 | c.602A>C p.E201A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54564208, COSV54564769; called by muse, mutect2, varscan2
- CARNS1 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57129968; called by mutect2, varscan2
- CASK | c.2434G>A p.E812K (on ENST00000378163 / NM_001367721.1; = p.E807K on NM_003688.3) | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1235769310, COSV100587326; called by muse, mutect2, varscan2
- CASK | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.51); catalogued as COSV100587327; called by muse, mutect2
- CASK | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as CS090757, COSV59361325; called by muse, mutect2, varscan2
- CASP1 | c.487C>T p.R163C (on ENST00000436863 / NM_033292.4; = p.R142C on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752283506, COSV62056069, COSV62057461; called by muse, mutect2, varscan2
- CASP8 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51847352, COSV51857450; called by muse, mutect2, varscan2
- CBLN1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV54653505; called by mutect2, varscan2
- CBLN2 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54050503, COSV99504185; called by muse, mutect2, varscan2
- CBX3 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV61761254; called by muse, mutect2, varscan2
- CCDC112 | c.1146A>C p.Q382H | Missense Mutation (SNP) | VAF 101/532 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65472760; called by muse, mutect2, varscan2
- CCDC115 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170400086, COSV52091228; called by muse, mutect2, varscan2
- CCDC125 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs528487517, COSV67287741, COSV67287887; called by muse, mutect2, varscan2
- CCDC141 | c.2041A>C p.K681Q | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99836929; called by muse, mutect2, varscan2
- CCDC141 | c.1894A>C p.N632H | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV55370496; called by muse, mutect2, varscan2
- CCDC144A | c.2803G>T p.D935Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV60696952; called by muse, mutect2, varscan2
- CCDC146 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs371350411; called by muse, mutect2, varscan2
- CCDC146 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.198); catalogued as rs1192974559, COSV53544201, COSV53548881; called by muse, mutect2, varscan2
- CCDC15 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV100776985; called by muse, mutect2
- CCDC15 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); catalogued as COSV61080690; called by muse, mutect2, varscan2
- CCDC160 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs866157840, COSV66251350; called by muse, mutect2, varscan2
- CCDC180 | c.4756C>A p.L1586I | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV63827726; called by muse, mutect2, varscan2
- CCDC34 | c.828T>G p.F276L | Missense Mutation (SNP) | VAF 179/507 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100156601; called by muse, mutect2
- CCDC66 | c.2719C>T p.R907* (on ENST00000394672 / NM_001353147.1; = p.R873* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/169 reads (15%) | catalogued as rs374852204; called by muse, mutect2, varscan2
- CCDC73 | c.1341dup p.E448Rfs*12 | Frame Shift Ins (INS) | VAF 42/161 reads (26%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88C | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101105770; called by muse, mutect2
- CCDC92 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs143142884; called by muse, mutect2, varscan2
- CCER1 | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs528219668, COSV62646491, COSV62648654; called by muse, varscan2
- CCER1 | c.1070T>A p.F357Y | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV62646201; called by muse, varscan2
- CCKAR | c.786A>C p.K262N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV55160347; called by muse, mutect2, varscan2
- CCL20 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 12/209 reads (6%) | catalogued as COSV100721832; called by muse, mutect2
- CCNB3 | c.1878G>T p.M626I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52070876, COSV52073188; called by mutect2, varscan2
- CCNJL | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57443326; called by muse, mutect2, varscan2
- CCNT2 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51471445; called by muse, mutect2, varscan2
- CCNY | c.459G>A p.S153= | Splice Region (SNP) | VAF 14/340 reads (4%) | catalogued as rs1207381634, COSV55187483; called by muse, mutect2
- CCPG1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1485834962, COSV51241189; called by muse, mutect2, varscan2
- CCR4 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 26/605 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV100447418; called by muse, mutect2
- CCT6B | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58488189; called by muse, varscan2
- CCT6B | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV100031087, COSV58488198; called by muse, mutect2, varscan2
- CCZ1 | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 17/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58073710; called by muse, mutect2
- CD244 | c.1069C>T p.R357* (on ENST00000368033 / NM_001166663.2; = p.R352* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 64/180 reads (36%) | catalogued as rs138354575; called by muse, mutect2, varscan2
- CD3D | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs777721098, COSV56140079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD55 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as CM076088, COSV58576670; called by muse, mutect2, varscan2
- CD8B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as rs1472668619, COSV100514797; called by muse, mutect2
- CDC14A | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs778051201, COSV60556049; called by muse, mutect2, varscan2
- CDC20B | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV57050383; called by muse, mutect2, varscan2
- CDC27 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV50367727; called by muse, mutect2, varscan2
- CDC40 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 71/299 reads (24%) | catalogued as COSV57008246; called by muse, mutect2, varscan2
- CDCA7L | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as rs763777079, COSV60944686; called by muse, mutect2, varscan2
- CDH12 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101202754, COSV104428502; called by muse, mutect2
- CDH18 | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV99935630; called by muse, mutect2
- CDH18 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56904772, COSV56951515; called by muse, mutect2, varscan2
- CDH24 | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52974211; called by muse, mutect2, varscan2
- CDH8 | c.823A>C p.K275Q | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV54853814; called by muse, mutect2, varscan2
- CDIN1 | c.439G>A p.D147N (on ENST00000437989; = p.D49N on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371227376; called by muse, mutect2
- CDK19 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs199931376, COSV60447644; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1806G>T p.Q602H | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV62572735; called by muse, mutect2, varscan2
- CDKL1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV53578006, COSV53578351; called by muse, mutect2, varscan2
- CDKL4 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV101115330; called by muse, mutect2
- CDS1 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55687037; called by muse, mutect2, varscan2
- CEACAM4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782776170, COSV55730911; called by muse, mutect2, varscan2
- CEBPZ | c.2705C>A p.S902Y | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305258; called by muse, mutect2
- CENPC | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV56621767; called by muse, varscan2
- CENPE | c.6906C>A p.F2302L | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54377640; called by muse, mutect2, varscan2
- CENPE | c.5788C>T p.R1930C | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs780081164, COSV54376417; called by muse, mutect2, varscan2
- CENPE | c.2635A>G p.T879A | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV54377669; called by muse, mutect2, varscan2
- CENPI | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54501254, COSV54503958, COSV54506956; called by muse, mutect2, varscan2
- CEP128 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1208632035, COSV53673087; called by muse, mutect2, varscan2
- CEP290 | c.5953G>T p.E1985* | Nonsense Mutation (SNP) | VAF 119/377 reads (32%) | catalogued as rs1014354752, COSV58349703; called by muse, mutect2, varscan2
- CEP350 | c.6007T>C p.S2003P | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV62599724; called by muse, mutect2, varscan2
- CEP350 | c.6724C>A p.L2242I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV62599731, COSV62601853; called by muse, mutect2, varscan2
- CEP78 | c.1789A>C p.N597H (on ENST00000424347 / NM_001349840.2; = p.N598H on NM_032171.3) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52845955; called by muse, mutect2, varscan2
- CEP78 | c.2049G>T p.K683N (on ENST00000424347 / NM_001349840.2; = p.K684N on NM_032171.3) | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as COSV52845968; called by muse, mutect2, varscan2
- CEP97 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV59123248; called by muse, mutect2, varscan2
- CEP97 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59123261; called by muse, mutect2, varscan2
- CERKL | c.848G>A p.R283Q (on ENST00000339098 / NM_001030311.2; = p.R257Q on NM_201548.5) | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762961333, COSV59203100; called by muse, mutect2, varscan2
- CERS4 | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV99250660; called by muse, mutect2
- CFAP206 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99739695; called by muse, varscan2
- CFAP251 | c.3022A>T p.N1008Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV99996181; called by muse, mutect2, varscan2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 43/200 reads (22%) | catalogued as rs140641107; called by muse, mutect2, varscan2
- CFAP43 | c.4421C>A p.S1474Y | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV63852368, COSV63853053; called by muse, mutect2, varscan2
- CFAP47 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 48/226 reads (21%) | catalogued as COSV52881738; called by muse, mutect2, varscan2
- CFAP47 | c.5415C>A p.F1805L | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100545414; called by muse, mutect2
- CFAP57 | c.329T>G p.F110C | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV65263865; called by muse, mutect2, varscan2
- CHCHD3 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52771284; called by muse, mutect2, varscan2
- CHCHD3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 33/217 reads (15%) | catalogued as COSV52771293; called by muse, mutect2, varscan2
- CHCHD4 | c.376G>T p.E126* (on ENST00000396914 / NM_001098502.2; = p.E139* on NM_144636.3) | Nonsense Mutation (SNP) | VAF 21/418 reads (5%) | catalogued as COSV99853959; called by muse, mutect2
- CHD1 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs951793419, COSV99399531; called by muse, mutect2
- CHD3 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57872876; called by muse, mutect2, varscan2
- CHD9 | c.4807C>T p.R1603* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs1353837906, COSV99528663; called by muse, mutect2
- CHORDC1 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57705590; called by muse, mutect2, varscan2
- CHRDL1 | c.1126C>T p.R376* (on ENST00000372045; = p.R382* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 37/193 reads (19%) | catalogued as rs898698529, COSV54322916; called by muse, mutect2, varscan2
- CHRDL1 | c.509G>A p.R170Q (on ENST00000372045; = p.R176Q on NM_145234.4) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.239); catalogued as rs368442413, COSV54323469, COSV99487727; called by muse, varscan2
- CHRDL1 | c.128G>T p.R43I (on ENST00000372045; = p.R49I on NM_145234.4) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV99488268; called by muse, mutect2, varscan2
- CHRM5 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749608809, COSV67246897; called by muse, mutect2, varscan2
- CHRNB3 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51492976; called by muse, mutect2, varscan2
- CHRNB3 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759422009, COSV51493825; called by muse, mutect2, varscan2
- CHST8 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as rs200926968; called by muse, mutect2, varscan2
- CHST9 | c.252T>G p.F84L | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99410274; called by muse, mutect2
- CHTOP | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as rs946183413, COSV64154932; called by muse, mutect2, varscan2
- CINP | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV53736194; called by muse, mutect2, varscan2
- CIT | c.967A>C p.K323Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV55862827; called by muse, varscan2
- CKAP5 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV56365025; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV50451098; called by muse, varscan2
- CLASP1 | c.683A>C p.K228T | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV55316722; called by muse, mutect2, varscan2
- CLASP2 | c.3410C>T p.S1137L (on ENST00000359576; = p.S1136L on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV100223596; called by muse, mutect2
- CLCA2 | c.2445T>G p.F815L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100991572; called by muse, mutect2, varscan2
- CLCN1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546411827, CM110920, COSV58368188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN5 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV56582820; called by muse, mutect2, varscan2
- CLCN5 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV56582833; called by muse, mutect2, varscan2
- CLEC12A | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58560636; called by muse, mutect2, varscan2
- CLEC17A | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.672); catalogued as COSV60429176; called by muse, mutect2, varscan2
- CLEC4F | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99713776; called by muse, mutect2, varscan2
- CLMN | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs375694132; called by muse, mutect2, varscan2
- CLTRN | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV66711695; called by muse, mutect2, varscan2
- CMA1 | c.198T>G p.H66Q | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV51625057; called by muse, mutect2, varscan2
- CMAS | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV57556197; called by muse, mutect2, varscan2
- CNGA1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 13/180 reads (7%) | catalogued as COSV100652242; called by muse, mutect2
- CNGB3 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV60686194; called by muse, mutect2, varscan2
- CNKSR2 | c.1208T>A p.F403Y | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99668818; called by muse, mutect2
- CNKSR2 | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65278839; called by muse, mutect2
- CNOT1 | c.6134G>A p.R2045Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55314117; called by muse, mutect2, varscan2
- CNOT1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs768422744, COSV57766312; called by muse, mutect2
- CNOT6 | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56159657; called by muse, mutect2, varscan2
- CNTLN | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99264458; called by muse, mutect2
- CNTN4 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs183942017, COSV61869453; called by muse, mutect2, varscan2
- CNTN5 | c.3236C>A p.S1079Y | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54318630, COSV99677873; called by muse, mutect2
- CNTNAP2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs794727802, COSV62203066; ClinVar: uncertain significance; called by muse, mutect2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- COA1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs751652291, COSV56240710; called by muse, mutect2, varscan2
- COG2 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV64186158; called by muse, mutect2, varscan2
- COG3 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV63071614; called by muse, mutect2, varscan2
- COG6 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV62995280; called by muse, mutect2, varscan2
- COL11A2 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776656481, COSV59494470; called by muse, mutect2, varscan2
- COL14A1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52848487; called by muse, mutect2
- COL19A1 | c.3302-1G>T p.X1101_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100506482; called by muse, mutect2
- COL20A1 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as rs770819951, COSV58925894; called by muse, mutect2
- COL3A1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV58583826; called by muse, mutect2, varscan2
- COL4A4 | c.2170C>A p.R724S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV61630234, COSV61630282; called by muse, mutect2, varscan2
- COL5A1 | c.1355A>C p.K452T | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65666374; called by muse, varscan2
- COL6A3 | c.9231G>T p.K3077N | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs946842388, COSV55082584, COSV99798214; called by muse, mutect2, varscan2
- COL6A6 | c.3074C>A p.S1025Y | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100650339, COSV62027864; called by muse, mutect2
- COX20 | c.282A>C p.E94D | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV100834675; called by muse, mutect2
- COX6C | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs201229067, COSV52553321; called by muse, mutect2, varscan2
- CP | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | catalogued as COSV52829905, COSV52830422; called by muse, mutect2
- CPA1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs782556361, COSV50568327; called by muse, varscan2
- CPNE9 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339411154, COSV56067876; called by muse, mutect2, varscan2
- CPT1C | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 42/139 reads (30%) | catalogued as COSV54918121; called by muse, mutect2, varscan2
- CPXCR1 | c.647A>C p.K216T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV52161424; called by muse, mutect2, varscan2
- CREB5 | c.1345G>T p.E449* (on ENST00000357727 / NM_182898.4; = p.E442* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 46/163 reads (28%) | catalogued as COSV63218291; called by muse, mutect2, varscan2
- CRISP1 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV59993016; called by muse, mutect2, varscan2
- CRNN | c.365A>C p.E122A | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV55121079; called by muse, mutect2, varscan2
- CRYBG1 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64811152; called by muse, mutect2, varscan2
- CSE1L | c.2514G>T p.E838D | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV99522062; called by muse, mutect2
- CSF3R | c.2054T>C p.L685P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58964290; called by mutect2, varscan2
- CSMD1 | c.8377C>T p.R2793* (on ENST00000520002; = p.R2792* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59294071; called by muse, mutect2, varscan2
- CSMD1 | c.5900C>T p.P1967L (on ENST00000520002; = p.P1966L on NM_033225.6) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866503043, COSV59294091, COSV59352292; called by muse, mutect2, varscan2
- CSMD1 | c.4627C>T p.R1543W (on ENST00000520002; = p.R1542W on NM_033225.6) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59278132; called by muse, mutect2, varscan2
- CSMD1 | c.2345C>A p.S782Y (on ENST00000520002; = p.S781Y on NM_033225.6) | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs766601526, COSV59294145; called by muse, varscan2
- CSMD1 | c.1439C>T p.S480L (on ENST00000520002; = p.S479L on NM_033225.6) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs370398160; called by muse, mutect2, varscan2
- CSMD3 | c.7793G>A p.R2598Q (on ENST00000297405 / NM_001363185.1; = p.R2494Q on NM_052900.3) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as rs139482857; called by mutect2, varscan2
- CSMD3 | c.1777G>T p.E593* (on ENST00000297405 / NM_001363185.1; = p.E489* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 41/166 reads (25%) | catalogued as COSV52124977; called by muse, mutect2, varscan2
- CTAGE6 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 22/327 reads (7%) | catalogued as COSV101417855; called by muse, mutect2
- CTCF | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV50462746, COSV50538550; called by muse, mutect2, varscan2
- CTCF | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV50462752; called by muse, mutect2, varscan2
- CTCFL | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs755537284, COSV54771671; called by muse, mutect2, varscan2
- CTHRC1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as rs374084026; called by muse, mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 64/226 reads (28%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.546A>C p.E182D | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.973); catalogued as COSV57717720; called by muse, varscan2
- CTNNBL1 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1446320372, COSV63745672; called by muse, mutect2
- CTTNBP2 | c.1670C>A p.S557Y | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50391616; called by muse, mutect2, varscan2
- CTXN3 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101060707, COSV65218087; called by muse, mutect2, varscan2
- CUL4B | c.1208A>C p.K403T | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV60685553; called by muse, varscan2
- CXCL1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67611515; called by muse, mutect2
- CXCL12 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59109376; called by muse, mutect2
- CYLC1 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | catalogued as COSV61410628; called by muse, mutect2, varscan2
- CYP11A1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV51431031; called by muse, mutect2, varscan2
- CYP11A1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs952740494, COSV51431045; called by muse, mutect2, varscan2
- CYP11B1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1304494959, COSV52825464, COSV52828663; called by muse, mutect2, varscan2
- CYP2C18 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1432799997, COSV99608601; called by muse, mutect2
- CYP2C8 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64875956; called by muse, mutect2, varscan2
- CYP2C8 | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs758378725, COSV64876295, COSV64878505; called by muse, mutect2, varscan2
- CYP2U1 | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV60548252; called by muse, varscan2
- CYP4F11 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | catalogued as COSV56125981; called by muse, mutect2, varscan2
- CYP4F11 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV56125991; called by muse, mutect2, varscan2
- CYSLTR1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64819375; called by muse, mutect2, varscan2
- CYTH3 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV63440607; called by muse, mutect2
- CYTH4 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV50631533; called by muse, varscan2
- CYTIP | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs763717313, COSV51632338; called by muse, mutect2, varscan2
- DAB2 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV57919802; called by muse, mutect2
- DAB2 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100297894, COSV100298061; called by muse, mutect2
- DAB2IP | c.2147C>T p.S716F (on ENST00000408936; = p.S688F on NM_032552.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs747456330, COSV52255790; called by muse, mutect2, varscan2
- DAW1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV59364190; called by muse, mutect2, varscan2
- DBT | c.1007T>G p.I336R | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV64495042; called by muse, mutect2, varscan2
- DCAF4L1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs973927928, COSV60786385; called by muse, mutect2, varscan2
- DCAF6 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV56575980; called by muse, mutect2, varscan2
- DCANP1 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as COSV101538253; called by muse, mutect2, varscan2
- DCBLD1 | c.1170A>C p.R390S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51639019; called by muse, mutect2, varscan2
- DCDC1 | c.2852C>T p.S951F (on ENST00000597505 / NM_001367979.1; = p.S58F on NM_020869.3) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV100338381; called by muse, mutect2, varscan2
- DCHS1 | c.1811A>G p.D604G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55032011; called by muse, mutect2, varscan2
- DCUN1D2 | c.471T>G p.F157L | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs1339925150, COSV60260855; called by muse, mutect2, varscan2
- DDHD2 | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV101240678; called by muse, mutect2
- DDIAS | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs1474343420, COSV61271660; called by muse, mutect2, varscan2
- DDX11 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1221152082, COSV52500765; called by muse, mutect2, varscan2
- DDX17 | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99318248; called by muse, mutect2
- DDX24 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 87/408 reads (21%) | catalogued as COSV58211786, COSV58211826; called by muse, mutect2, varscan2
- DDX46 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1202463050, COSV62801219; called by muse, mutect2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2, varscan2
- DDX51 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1192145074, COSV57957539; called by muse, mutect2, varscan2
- DDX58 | c.800-2A>C p.X267_splice | Splice Site (SNP) | VAF 18/113 reads (16%) | catalogued as COSV65882496; called by muse, mutect2, varscan2
- DEFB131A | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs771498069, COSV58416077; called by muse, mutect2, varscan2
- DENND4A | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV71265361; called by muse, mutect2, varscan2
- DENND4A | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 27/277 reads (10%) | catalogued as COSV101475360; called by muse, mutect2, varscan2
- DENND6B | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764912026, COSV69806677; called by muse, mutect2, varscan2
- DERL2 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50146993, COSV50147446; called by muse, mutect2, varscan2
- DGAT2 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99929815; called by muse, mutect2
- DGKB | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.51); catalogued as rs1323248378, COSV51767863; called by muse, mutect2, varscan2
- DGKI | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55965242; called by muse, mutect2
- DGKK | c.3247C>T p.R1083W | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1557223887, COSV101053038; called by muse, mutect2, varscan2
- DGKK | c.756G>A p.A252= | Splice Region (SNP) | VAF 12/225 reads (5%) | catalogued as rs782706024, COSV101052880, COSV101053039; called by muse, mutect2
- DHX15 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.041); catalogued as rs1333526601, COSV100391446; called by muse, mutect2
- DHX35 | c.1464G>T p.L488F | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV52668290; called by muse, mutect2, varscan2
- DHX9 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100841425; called by muse, mutect2
- DIAPH3 | c.697A>C p.K233Q | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV57366336; called by muse, mutect2, varscan2
- DIP2C | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs1454127875, COSV55149729; called by muse, mutect2, varscan2
- DIPK2B | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs749712350, COSV101211642; called by mutect2, varscan2
- DMD | c.6148G>T p.G2050C | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100820150; called by muse, mutect2
- DMD | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as rs128626249, CM087401, CM930194, COSV63737423; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- DMD | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 26/302 reads (9%) | catalogued as CM973023, COSV63734722; called by muse, mutect2
- DMXL1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 76/217 reads (35%) | catalogued as COSV60706443; called by muse, mutect2, varscan2
- DMXL1 | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224207; called by muse, mutect2
- DMXL1 | c.2768T>G p.L923R | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV60706452; called by muse, mutect2, varscan2
- DMXL1 | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs776741081, COSV60705181; called by muse, mutect2, varscan2
- DMXL2 | c.2063A>C p.K688T | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1224043077, COSV51842163; called by muse, varscan2
- DMXL2 | c.265A>C p.N89H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV51840597; called by muse, mutect2, varscan2
- DNAAF4 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763105304, COSV58247154; called by muse, mutect2, varscan2
- DNAH1 | c.7174G>T p.E2392* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV101327588, COSV70227097; called by muse, mutect2, varscan2
- DNAH10 | c.4477G>A p.E1493K (on ENST00000409039; = p.E1432K on NM_207437.3) | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs373563221, COSV68989561; called by muse, mutect2, varscan2
- DNAH10 | c.4868G>T p.R1623I (on ENST00000409039; = p.R1562I on NM_207437.3) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101292153, COSV68989564; called by muse, varscan2
- DNAH10 | c.5002G>A p.G1668S (on ENST00000409039; = p.G1607S on NM_207437.3) | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.22); catalogued as rs762922513, COSV68989113; called by muse, mutect2, varscan2
- DNAH11 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 24/135 reads (18%) | catalogued as COSV60944633; called by muse, mutect2, varscan2
- DNAH11 | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 56/316 reads (18%) | catalogued as rs1447609804, COSV60940698; called by muse, mutect2, varscan2
- DNAH11 | c.4095+8C>A | Splice Region (SNP) | VAF 10/248 reads (4%) | catalogued as COSV100178774, COSV100179474; called by muse, mutect2
- DNAH11 | c.5500C>T p.R1834C | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs180897552, CM140771, COSV60944662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.11193C>A p.F3731L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60944672; called by muse, mutect2, varscan2
- DNAH11 | c.11761G>A p.E3921K | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs774963422, COSV60944680; called by muse, mutect2, varscan2
- DNAH14 | c.729G>T p.L243F (on ENST00000445597; = p.L66F on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.2); catalogued as COSV64780764; called by muse, mutect2, varscan2
- DNAH2 | c.3626T>C p.I1209T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV66717457; called by muse, mutect2, varscan2
- DNAH5 | c.3784G>T p.E1262* | Nonsense Mutation (SNP) | VAF 44/204 reads (22%) | catalogued as COSV54210192, COSV54243654; called by muse, varscan2
- DNAH9 | c.8041G>T p.D2681Y | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339268, COSV52382416; called by muse, mutect2, varscan2
- DNAH9 | c.8988C>A p.F2996L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV52337276, COSV99306263; called by muse, mutect2
- DNAI2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); catalogued as COSV56757360; called by muse, mutect2, varscan2
- DNAJC13 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1232607951, COSV53447059; called by muse, varscan2
- DNMT3B | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as rs1182001726, COSV52416573; called by muse, mutect2
- DOCK1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99730313; called by muse, mutect2
- DOCK10 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51356913; called by muse, mutect2, varscan2
- DOCK11 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99354033; called by muse, mutect2
- DOCK2 | c.2066T>G p.F689C | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99912998; called by muse, mutect2
- DOCK5 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs769071784, COSV52397464; called by muse, mutect2, varscan2
- DOP1B | c.6103T>C p.F2035L | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67692455; called by muse, varscan2
- DPAGT1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62614080; called by muse, mutect2, varscan2
- DPP4 | c.2080A>C p.N694H | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV62104695; called by muse, mutect2
- DPP8 | c.2036A>C p.N679T (on ENST00000341861 / NM_001320875.2; = p.N663T on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV55676742; called by muse, mutect2, varscan2
- DPY19L3 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as COSV100639204; called by muse, mutect2
- DRAXIN | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs746412453, COSV53842172; called by muse, mutect2, varscan2
- DRD2 | c.539A>C p.N180T | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100669753; called by muse, mutect2
- DRP2 | c.2203A>C p.N735H | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV65809529; called by muse, mutect2, varscan2
- DSC3 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100844613; called by muse, mutect2
- DSCAM | c.4399G>T p.E1467* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV68022671; called by muse, mutect2
- DSEL | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV59489958; called by muse, mutect2, varscan2
- DSEL | c.1022A>C p.D341A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59489967; called by muse, mutect2, varscan2
- DSG1 | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57139291, COSV99936107; called by muse, mutect2
- DSG1 | c.2241C>A p.F747L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV57134832, COSV57137505; called by muse, mutect2
- DSG4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | catalogued as rs1384407099, COSV57390566; called by muse, mutect2
- DSG4 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100355974; called by muse, mutect2
- DSN1 | c.643A>C p.I215L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV65518667; called by muse, mutect2, varscan2
- DSP | c.7374G>T p.K2458N | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs778068911, COSV65791713; called by muse, mutect2, varscan2
- DSPP | c.3602G>A p.S1201N | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.206); catalogued as COSV99217474; called by muse, mutect2
- DST | c.9118G>A p.E3040K | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV99757135; called by muse, mutect2, varscan2
- DTNA | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as rs1320555032, COSV51994365; called by muse, mutect2, varscan2
- DTX1 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs747945791, COSV57496012; called by muse, mutect2, varscan2
- DUOX2 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs367803824, COSV66530997; called by muse, mutect2, varscan2
- DUSP10 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs779913097, COSV60456419, COSV60456841; called by muse, mutect2, varscan2
- DUSP5 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV63645356; called by muse, mutect2, varscan2
- DYNC1I1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV61457338; called by muse, varscan2
- DYRK1A | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100117945, COSV58292283; called by muse, mutect2
- DYRK4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1232724867, COSV99156646; called by muse, mutect2
- DZIP1L | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV59519610; called by muse, mutect2, varscan2
- E2F6 | c.224T>G p.F75C | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100215353; called by muse, mutect2
- EBLN2 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.322); catalogued as COSV55594497; called by muse, varscan2
- ECT2 | c.2009G>A p.R670Q (on ENST00000392692 / NM_001349098.2; = p.R639Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766221474, COSV51686991; called by muse, mutect2, varscan2
- ECT2L | c.2645A>G p.E882G | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57809181; called by muse, mutect2, varscan2
- EEF1E1 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65675347; called by muse, mutect2, varscan2
- EEF2 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); catalogued as rs767823532, COSV58578765; called by mutect2, varscan2
- EFCAB5 | c.1559G>T p.R520I | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs560863696, COSV57927020; called by muse, mutect2, varscan2
- EFHB | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 20/347 reads (6%) | catalogued as COSV99859679; called by muse, mutect2
- EFHC2 | c.1887G>T p.K629N | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59092494; called by muse, mutect2, varscan2
- EFL1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs372161887; called by muse, mutect2, varscan2
- EGF | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs185277473, COSV54476698; called by muse, mutect2, varscan2
- EGFL6 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV63633131; called by muse, mutect2, varscan2
- EGFLAM | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59294209, COSV59301298; called by muse, mutect2
- EHBP1 | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 14/216 reads (6%) | catalogued as COSV99861096; called by muse, mutect2
- EHBP1L1 | c.1826A>G p.E609G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58571889; called by muse, mutect2, varscan2
- EID2 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV66810805; called by muse, mutect2, varscan2
- EIF2AK1 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 48/165 reads (29%) | catalogued as COSV52237025, COSV52238792; called by muse, mutect2, varscan2
- EIF3A | c.2275T>G p.L759V | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV64960706; called by muse, mutect2, varscan2
- EIF3C | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs767062124, COSV100528147; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57515050; called by muse, mutect2, varscan2
- EIF4G3 | c.4021G>T p.E1341* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV51676311; called by muse, mutect2, varscan2
- EIF4G3 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 41/210 reads (20%) | catalogued as COSV51676328; called by muse, mutect2, varscan2
- EIF5 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs144699320, COSV99384873; called by muse, mutect2, varscan2
- ELMO1 | c.1808C>A p.S603Y | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs1486846711, COSV100164785, COSV60322689; called by muse, mutect2
- ELOVL2 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV61154396; called by muse, mutect2, varscan2
- ELP1 | c.3326T>C p.V1109A | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101010422; called by muse, mutect2
- EMC2 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV55208384; called by muse, mutect2, varscan2
- EMP1 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56998388; called by muse, mutect2, varscan2
- EMX1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408368285, COSV99252521; called by muse, mutect2, varscan2
- ENAH | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52865876; called by muse, mutect2, varscan2
- ENC1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs985000520, COSV56628865; called by muse, mutect2, varscan2
- ENGASE | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748638220, COSV56134310; called by muse, mutect2, varscan2
- ENKUR | c.589T>G p.L197V | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100482152; called by muse, mutect2
- ENPEP | c.2660G>T p.R887I | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54448015, COSV54458861; called by muse, varscan2
- ENPP3 | c.628T>G p.Y210D | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100717416; called by muse, mutect2
- ENTPD3 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57193619; called by muse, mutect2, varscan2
- ENTPD7 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs759561702, COSV65112053; called by muse, mutect2, varscan2
- EP300 | c.3853G>T p.E1285* | Nonsense Mutation (SNP) | VAF 58/250 reads (23%) | catalogued as COSV54328422; called by muse, mutect2, varscan2
- EPC2 | c.218T>G p.V73G | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51541303; called by muse, mutect2, varscan2
- EPC2 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.163); catalogued as COSV51541315; called by muse, mutect2, varscan2
- EPG5 | c.5079C>A p.F1693L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.716); catalogued as COSV99957452; called by muse, mutect2
- EPG5 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99957453; called by muse, mutect2
- EPHA3 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs964408959, COSV60727177; called by muse, mutect2
- EPHA3 | c.1765A>C p.K589Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV60697564; called by muse, mutect2, varscan2
- EPHA5 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as COSV56652439, COSV99899377; called by muse, mutect2
- EPHA6 | c.3363G>A p.M1121I | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.137); catalogued as rs1314561697, COSV101063350; called by muse, mutect2
- EPSTI1 | c.658-1G>T p.X220_splice | Splice Site (SNP) | VAF 18/182 reads (10%) | catalogued as COSV58044375; called by muse, mutect2, varscan2
- EPX | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376090047; called by muse, mutect2, varscan2
- EQTN | c.275T>G p.F92C | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101192380; called by muse, mutect2
- EQTN | c.6T>G p.N2K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV101192381; called by mutect2, varscan2
- ERBB4 | c.3184-1G>T p.X1062_splice | Splice Site (SNP) | VAF 5/96 reads (5%) | catalogued as rs1553519044, COSV100724062, COSV61462797; called by muse, mutect2
- ERC2 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as rs1021045198; called by muse, mutect2
- ERC2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs757289425, COSV55604382; called by muse, mutect2, varscan2
- ERCC4 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61314029, COSV61314126; called by muse, mutect2
- ERCC4 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180030515, COSV100318927; called by muse, mutect2
- ERCC6L2 | c.3311C>T p.S1104L | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs372436741; called by muse, varscan2
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 84/428 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by muse, varscan2
- ERMN | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 69/188 reads (37%) | catalogued as COSV68075054; called by muse, mutect2, varscan2
- ERVW-1 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as COSV71259348; called by muse, varscan2
- ESRP1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 16/248 reads (6%) | catalogued as COSV64409346, COSV64412577; called by muse, mutect2
- ESRRB | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1450349797, COSV99835357; called by muse, mutect2
- ETAA1 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55472333; called by muse, mutect2, varscan2
- ETV4 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV52251544; called by muse, mutect2, varscan2
- EXOC1 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as COSV62119434; called by muse, mutect2, varscan2
- EXOC3 | c.1526G>T p.R509I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs1220428036, COSV100155347, COSV100155567; called by muse, mutect2, varscan2
- EXOC3L2 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs770466337, COSV52972307; called by muse, mutect2, varscan2
- EXOC8 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1366563567, COSV50477683; called by muse, varscan2
- EXPH5 | c.5744T>G p.F1915C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56199666; called by muse, mutect2, varscan2
- EYA1 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 71/330 reads (22%) | catalogued as COSV58158382; called by muse, mutect2, varscan2
- EYA4 | c.1249G>T p.E417* (on ENST00000531901 / NM_001301013.1; = p.E411* on NM_004100.5) | Nonsense Mutation (SNP) | VAF 39/192 reads (20%) | catalogued as COSV62047479, COSV62052492; called by muse, mutect2, varscan2
- F10 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as rs867593753, COSV65021005; called by muse, mutect2, varscan2
- F13B | c.1172-1G>T p.X391_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100803315, COSV100803482; called by muse, mutect2
- F2 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV61315043; called by mutect2, varscan2
- F5 | c.6264G>T p.K2088N | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV63121661, COSV63123673; called by muse, mutect2, varscan2
- F5 | c.3449C>A p.S1150Y | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100889134; called by muse, mutect2
- F8 | c.3652G>T p.E1218* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as CD080846, COSV64270454; called by muse, mutect2, varscan2
- F8 | c.1824G>T p.E608D | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100811590; called by muse, mutect2
- FABP2 | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99916943; called by muse, mutect2
- FAF1 | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.437); catalogued as COSV65636724, COSV65637038; called by muse, mutect2, varscan2
- FAF1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1344381654, COSV65637039; called by muse, mutect2, varscan2
- FAM120A | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV99465742; called by muse, mutect2
- FAM124A | c.1311C>A p.F437L (on ENST00000322475 / NM_001242312.2; = p.F473L on NM_145019.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV54474815; called by mutect2, varscan2
- FAM126A | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as COSV69471307; called by muse, mutect2, varscan2
- FAM135B | c.3534G>T p.K1178N | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV52711541, COSV99424651; called by muse, mutect2, varscan2
- FAM166C | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV56599649; called by mutect2, varscan2
- FAM169A | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs762105709, COSV63063931; called by muse, mutect2, varscan2
- FAM177A1 | c.609A>C p.E203D (on ENST00000382406 / NM_001289022.2; = p.E226D on NM_173607.5) | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV54831735; called by muse, mutect2, varscan2
- FAM209A | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99711480, COSV99711658; called by muse, varscan2
- FAM209B | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64915095; called by muse, varscan2
- FAM214A | c.2229A>C p.K743N | Missense Mutation (SNP) | VAF 120/568 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV55922707; called by muse, mutect2, varscan2
- FAM81B | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1287248860, COSV99352926; called by muse, mutect2, varscan2
- FAM83B | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174562; called by muse, mutect2
- FAM91A1 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as rs1464094007, COSV100593633; called by muse, mutect2
- FAM98A | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.077); catalogued as COSV53209516; called by muse, mutect2, varscan2
- FAM9B | c.442A>G p.R148G | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100511045; called by muse, mutect2
- FANCB | c.947T>C p.F316S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60759125; called by muse, mutect2, varscan2
- FANCB | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV60758787, COSV60759134; called by muse, mutect2, varscan2
- FANCD2OS | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1280710958, COSV55034252; called by muse, mutect2, varscan2
- FASTKD2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99379027; called by muse, mutect2
- FAT2 | c.5383G>T p.E1795* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV55815197, COSV55829946; called by muse, varscan2
- FAT2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs748234388, COSV55815205; called by muse, mutect2, varscan2
- FAT2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.432); catalogued as rs1449378728, COSV55815214; called by muse, mutect2, varscan2
- FAT4 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV67882539; called by muse, mutect2, varscan2
- FAXC | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV67601652; called by muse, mutect2, varscan2
- FBXO30 | c.1418T>C p.M473T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV52790461; called by muse, mutect2, varscan2
- FBXO7 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 143/444 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770629287, COSV56676511; called by muse, mutect2, varscan2
- FCGR3A | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | catalogued as rs1042207; called by muse, mutect2, varscan2
- FEM1C | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1440575522, COSV57230948; called by muse, mutect2, varscan2
- FEZ1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 40/170 reads (24%) | catalogued as COSV54027148; called by muse, mutect2, varscan2
- FGA | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754195439, COSV100120135, COSV57393927; called by muse, mutect2, varscan2
- FGD4 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV56781315; called by muse, mutect2, varscan2
- FGD5 | c.1551G>T p.E517D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53239012; called by muse, mutect2, varscan2
- FGF1 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV100532394; called by muse, mutect2, varscan2
- FGF13 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59543637; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, varscan2
- FILIP1L | c.2278T>G p.L760V (on ENST00000354552 / NM_182909.3; = p.L520V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100496946; called by muse, mutect2
- FIZ1 | c.1437C>A p.F479L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55607293; called by muse, mutect2, varscan2
- FKTN | c.1125T>G p.D375E | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99795452; called by muse, mutect2
- FLNA | c.6175G>A p.E2059K (on ENST00000369850 / NM_001110556.2; = p.E2051K on NM_001456.3) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as rs782779958, COSV61039049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT3 | c.778A>G p.N260D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV53956496; called by muse, mutect2, varscan2
- FLT1 | c.3175-1G>A p.X1059_splice | Splice Site (SNP) | VAF 32/105 reads (30%) | catalogued as COSV56720931, COSV99030701; called by muse, mutect2, varscan2
- FLT1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201407326, COSV56720944; called by muse, varscan2
- FLT4 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99987353; called by muse, mutect2
- FMNL2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99979879; called by muse, mutect2
- FMNL3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs748305720, COSV53299018; called by muse, mutect2, varscan2
- FNBP1L | c.1498G>A p.E500K (on ENST00000271234 / NM_001164473.2; = p.E442K on NM_017737.5) | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV99554610; called by muse, mutect2
- FNDC1 | c.5398C>A p.L1800I | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51934855, COSV99796034; called by muse, mutect2
- FNIP1 | c.2626A>C p.K876Q | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.32); catalogued as COSV57194624; called by muse, mutect2, varscan2
- FOLH1 | c.191A>C p.E64A | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV57046709; called by muse, mutect2, varscan2
- FOXJ2 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1000445085, COSV50817638; called by muse, mutect2
- FOXR2 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs745735598, COSV59257969; called by muse, mutect2, varscan2
- FREM2 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV54831159; called by muse, mutect2, varscan2
- FRMD3 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418811; called by muse, mutect2
- FRMD5 | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68720752; called by muse, mutect2, varscan2
- FRS2 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV100166108; called by muse, mutect2
- FRY | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV66566624; called by muse, mutect2, varscan2
- FRY | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969375; called by muse, mutect2
- FSD1 | c.114G>A p.A38= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs771967101, COSV55694993, COSV55698017; called by mutect2, varscan2
- FST | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs202174134, COSV56814987; called by muse, mutect2
- FTCD | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52423956, COSV52428708; called by muse, mutect2, varscan2
- FXR2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs778622471, COSV51467784; called by muse, mutect2, varscan2
- G3BP1 | c.204A>C p.Q68H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV62365732; called by muse, mutect2, varscan2
- GAA | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV56407378; called by muse, mutect2, varscan2
- GABPB2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64460577; called by muse, mutect2, varscan2
2,199 further variants in this file (1,598 protein-altering or splice-affecting, 544 silent, 57 other) are not listed here.
